Somatic mutation profile of tumor specimen C3L-02841-01 (aliquot CPT0172130006) from CPTAC case C3L-02841, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G4; Age at diagnosis: 60.3 years (22,011 days).
Specimen C3L-02841-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ce2029e-a787-4828-aeb0-7cc394ea792d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02841-31 (Blood Derived Normal), aliquot CPT0167390002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e7b8fcec-af9b-4b82-ae0f-830ee866488d

The open-access MAF lists 51 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 9, Intron 5, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 2, In Frame Ins 2, RNA 2, 5'UTR 2, 3'Flank 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+1G>A p.X114_splice | Splice Site (SNP) | VAF 77/390 reads (20%) | hotspot (GDC flag); catalogued as rs730882032, CS044968, CS982396, COSV56543763, COSV56544858, COSV56545042, COSV56546938; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAP1 | c.1174del p.Q392Sfs*38 | Frame Shift Del (DEL) | VAF 69/298 reads (23%) | catalogued as COSV56238008; called by mutect2, pindel, varscan2
- GAL3ST2 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV51950180; called by muse, mutect2, varscan2
- INTS1 | c.5422C>G p.L1808V | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.553); catalogued as rs1382001310; called by muse, mutect2, varscan2
- LRRN2 | c.1453C>T p.R485W | Missense Mutation (SNP) | VAF 32/319 reads (10%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.917); catalogued as rs1407200785; called by muse, mutect2, varscan2
- NTAQ1 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV54876076; called by muse, mutect2, varscan2
- PCDHGB5 | c.1981G>A p.A661T | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV53960014; called by muse, mutect2, varscan2
- SALL1 | c.325G>C p.D109H | Missense Mutation (SNP) | VAF 94/526 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.445); catalogued as COSV99192446; called by muse, mutect2, varscan2
- SCN3A | c.4645G>A p.D1549N | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as rs866896540; called by muse, mutect2, varscan2
- TFAP2D | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 38/211 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867485486, COSV50466791; called by muse, mutect2, varscan2
- TRIM7 | c.1379G>A p.R460H | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1369813230; called by muse, mutect2
- ZSCAN18 | c.795A>T p.E265D | Missense Mutation (SNP) | VAF 24/144 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1053403378; called by muse, mutect2, varscan2
- C1orf94 | c.672C>A p.D224E (on ENST00000488417 / NM_001134734.2; = p.D34E on NM_032884.5) | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CDH10 | c.852delinsGG p.T286Hfs*10 | Frame Shift Ins (INS) | VAF 15/127 reads (12%) | called by pindel, varscan2*
- GALNT11 | c.1234-2A>T p.X412_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- GREB1 | c.4339T>C p.Y1447H | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- MIER1 | c.437_439del p.E146_I147delinsV (on ENST00000355356 / NM_001077701.3; = p.E163_I164delinsV on NM_020948.4 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 27/149 reads (18%) | called by mutect2, pindel, varscan2
- NLRC3 | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPIP5K2 | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRAM1 | c.105del p.K35Nfs*10 | Frame Shift Del (DEL) | VAF 28/170 reads (16%) | called by pindel, varscan2
- RC3H2 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2
- RMDN2 | c.628-7T>A | Splice Region (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- SAFB2 | c.1339dup p.A447Gfs*13 | Frame Shift Ins (INS) | VAF 44/310 reads (14%) | called by mutect2, pindel, varscan2
- TNP2 | c.122_124dup p.H41dup | In Frame Ins (INS) | VAF 53/333 reads (16%) | called by mutect2, pindel, varscan2
- TP73 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRIM6 | c.569T>C p.L190P | Missense Mutation (SNP) | VAF 106/528 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TTN | c.87919G>T p.A29307S (on ENST00000591111; = p.A21883S on NM_003319.4) | Missense Mutation (SNP) | VAF 22/209 reads (11%) | PolyPhen benign (0.134); called by muse, mutect2, varscan2
- WDFY3 | c.3397G>T p.E1133* | Nonsense Mutation (SNP) | VAF 16/384 reads (4%) | called by muse, mutect2
- ZNF318 | c.2973_2975dup p.S991_L992insF | In Frame Ins (INS) | VAF 43/247 reads (17%) | called by mutect2, pindel, varscan2
- ACLY | c.1632G>A p.G544= | Silent (SNP) | VAF 32/138 reads (23%) | catalogued as rs751690276; called by muse, mutect2, varscan2
- CDC7 | c.1110T>G p.V370= | Silent (SNP) | VAF 43/244 reads (18%) | called by muse, mutect2, varscan2
- GZMH | c.606C>T p.S202= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as rs756781704, COSV53538048; called by muse, mutect2, varscan2
- KRT14 | c.105G>A p.L35= | Silent (SNP) | VAF 39/197 reads (20%) | called by muse, mutect2, varscan2
- SHD | c.505C>A p.R169= | Silent (SNP) | VAF 37/201 reads (18%) | called by muse, mutect2, varscan2
- SMPD3 | c.807C>T p.N269= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs892110854, COSV54710136; called by muse, mutect2, varscan2
- SOX10 | c.1158C>T p.P386= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ZNF347 | c.276C>G p.L92= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- ZNF566 | c.1083T>C p.H361= | Silent (SNP) | VAF 15/82 reads (18%) | catalogued as rs1254644975; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501675 C>A | 5'Flank (SNP) | VAF 22/141 reads (16%) | called by muse, mutect2, varscan2
- CNTN4 | c.1358+1569G>T | Intron (SNP) | VAF 19/139 reads (14%) | catalogued as COSV61876685; called by muse, mutect2, varscan2
- CTSA | c.1165-9C>A | Intron (SNP) | VAF 47/270 reads (17%) | called by muse, mutect2, varscan2
- GPC1 | c.167-7886T>G | Intron (SNP) | VAF 33/213 reads (15%) | called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.835G>A | RNA (SNP) | VAF 20/490 reads (4%) | catalogued as rs782626217; called by muse, mutect2
- MAPK12 | c.314+303_314+314del | Intron (DEL) | VAF 39/297 reads (13%) | called by mutect2, pindel
- N4BP2L2 | chr13:32442843 G>A | 3'Flank (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- N4BP2L2 | chr13:32442844 C>G | 3'Flank (SNP) | VAF 15/102 reads (15%) | called by muse, mutect2, varscan2
- NKG7 | c.*8_*17del | 3'UTR (DEL) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- NT5C3A | c.354+27_354+28del | Intron (DEL) | VAF 11/98 reads (11%) | called by mutect2, pindel, varscan2
- PIP5KL1 | c.-16A>G | 5'UTR (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- POM121L4P | n.1001C>T | RNA (SNP) | VAF 98/572 reads (17%) | catalogued as rs1201363095; called by mutect2, varscan2
- TMEM225B | c.-10G>A | 5'UTR (SNP) | VAF 36/161 reads (22%) | catalogued as rs961263616; called by muse, mutect2, varscan2
